Somatic mutation profile of tumor specimen 0DQ80P from CCDI case PBCEFF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.8 years (6,151 days).
Specimen 0DQ80P: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0e651e98-6698-43b1-9980-46f62d91affc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQ7W7 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b4b70af2-7b34-4c34-ba32-0805c595d47e

The open-access MAF lists 38 somatic variants for this specimen: 30 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 6, Nonsense Mutation 2, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.103G>A p.G35R | Missense Mutation (SNP) | VAF 204/829 reads (25%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.773); catalogued as rs1553260624, COSV64731793, COSV64731830, COSV64732212; ClinVar: other; called by muse, varscan2
- PTPN11 | c.922A>G p.N308D | Missense Mutation (SNP) | VAF 88/568 reads (15%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.134); catalogued as rs28933386, CM013422, COSV61006575; ClinVar: pathogenic; called by muse, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 305/862 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, varscan2
- ARF3 | c.82G>A p.A28T | Missense Mutation (SNP) | VAF 116/704 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV56741604; called by muse, varscan2
- ATRX | c.5215C>T p.R1739* | Nonsense Mutation (SNP) | VAF 346/1098 reads (32%) | catalogued as COSV64873412; called by muse, varscan2
- BPTF | c.7001G>A p.R2334Q | Missense Mutation (SNP) | VAF 250/749 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs1480688167; called by muse, varscan2
- CPXM2 | c.214C>T p.R72C | Missense Mutation (SNP) | VAF 116/241 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.249); catalogued as rs962374194; called by muse, varscan2
- ERVV-2 | c.835C>T p.P279S | Missense Mutation (SNP) | VAF 208/654 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.027); catalogued as rs200390313; called by muse, varscan2
- FAM83H | c.2864C>T p.P955L | Missense Mutation (SNP) | VAF 192/558 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs555354517, COSV62029329; called by muse, varscan2
- NUDT10 | c.302C>T p.T101M | Missense Mutation (SNP) | VAF 85/853 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs146779225; called by muse, varscan2
- OR2T34 | c.712G>A p.G238S | Missense Mutation (SNP) | VAF 246/856 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.588); catalogued as rs779030084, COSV60901135, COSV60902204; called by muse, varscan2
- PPARGC1B | c.2551C>T p.R851C | Missense Mutation (SNP) | VAF 142/902 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.042); catalogued as rs1170753272; called by muse, varscan2
- PTEN | c.142A>G p.N48D | Missense Mutation (SNP) | VAF 232/590 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64298680; called by muse, varscan2
- SIK3 | c.823C>T p.R275C (on ENST00000445177 / NM_001366686.2; = p.R281C on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 152/1024 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV52614859; called by muse, varscan2
- SLC16A2 | c.634G>A p.A212T | Missense Mutation (SNP) | VAF 288/1029 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.459); catalogued as rs376266144; called by muse, varscan2
- SLC5A12 | c.353G>A p.R118Q | Missense Mutation (SNP) | VAF 184/1427 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1214460915, COSV54818659, COSV54818709; called by muse, varscan2
- STC1 | c.334C>T p.R112W | Missense Mutation (SNP) | VAF 152/1067 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1307541175, COSV51689304; called by muse, varscan2
- TTLL5 | c.331C>T p.R111C | Missense Mutation (SNP) | VAF 337/1110 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs761381633; called by muse, varscan2
- ABCB1 | c.1820T>C p.V607A | Missense Mutation (SNP) | VAF 368/1196 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.245); called by muse, varscan2
- ACSL4 | c.236T>G p.L79R (on ENST00000340800 / NM_022977.2; = p.L38R on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 366/1194 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, varscan2
- ARHGAP39 | c.1687G>A p.A563T | Missense Mutation (SNP) | VAF 147/438 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.398); called by muse, varscan2
- CCDC114 | c.24C>A p.Y8* | Nonsense Mutation (SNP) | VAF 88/570 reads (15%) | called by muse, varscan2
- CDCP2 | c.898C>A p.L300M | Missense Mutation (SNP) | VAF 44/369 reads (12%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.974); called by muse, varscan2
- FBXO43 | c.1916C>T p.P639L | Missense Mutation (SNP) | VAF 239/864 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- HS6ST2 | c.221C>T p.A74V | Missense Mutation (SNP) | VAF 156/461 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.018); called by muse, varscan2
- MYH2 | c.3047T>A p.L1016Q | Missense Mutation (SNP) | VAF 188/1516 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, varscan2
- SP140 | c.1862A>G p.K621R | Missense Mutation (SNP) | VAF 234/870 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.042); called by muse, varscan2
- TET2 | c.4979G>C p.R1660T | Missense Mutation (SNP) | VAF 70/566 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.388); called by muse, varscan2
- TLR10 | c.1776G>C p.L592F | Missense Mutation (SNP) | VAF 292/962 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.091); called by muse, varscan2
- UBTFL1 | c.739G>A p.V247M | Missense Mutation (SNP) | VAF 241/852 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, varscan2
- DCST2 | c.1917C>T p.S639= | Silent (SNP) | VAF 266/852 reads (31%) | catalogued as rs367722659; called by muse, varscan2
- ESX1 | c.1023C>T p.P341= | Silent (SNP) | VAF 180/826 reads (22%) | catalogued as rs1332049271; called by muse, varscan2
- LRRC3 | c.573G>A p.A191= | Silent (SNP) | VAF 129/315 reads (41%) | catalogued as rs147222046; called by muse, varscan2
- PDLIM5 | c.1764G>A p.K588= | Silent (SNP) | VAF 491/1043 reads (47%) | called by muse, varscan2
- USP43 | c.2562G>T p.T854= | Silent (SNP) | VAF 227/717 reads (32%) | catalogued as rs370287981, COSV53307233; called by muse, varscan2
- ZZEF1 | c.2787C>T p.V929= | Silent (SNP) | VAF 360/1058 reads (34%) | called by muse, varscan2
- FRMPD3 | c.*52C>A | 3'UTR (SNP) | VAF 41/167 reads (25%) | called by muse, varscan2
- MIA2 | c.-47C>G | 5'UTR (SNP) | VAF 22/96 reads (23%) | catalogued as rs756761883; called by muse, varscan2
